Gene-level copy-number profile of tumor specimen TCGA-63-A5MI-01A from TCGA case TCGA-63-A5MI, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA.
Specimen TCGA-63-A5MI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.394555db-8d47-458f-9013-669e5c6b6af3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5cf9c4f3-c6ab-4b54-b81a-a330d635506e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 1,927; copy number 2: 13,695; copy number 3: 17,878; copy number 4: 10,474; copy number 5: 9,077; copy number 6: 2,901; copy number 7: 2,264; copy number 8: 609; copy number 9: 71; copy number 10: 653; copy number 11: 45; copy number 13: 18; copy number 15: 63; copy number 16: 48; copy number 18: 3; copy number 20: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MI-01A-12D-A27J-01): tumor purity 0.47, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–25,844,585, 38 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241.
- chr19:40,771,648–41,062,444, 20 genes (within-gene range 0–4): MIA, MIA-RAB4B, RAB4B, RAB4B-EGLN2, AC008537.4, EGLN2, AC008537.1, CYP2T1P, CYP2F2P, AC008537.2, AC008537.3, CYP2A6, CYP2A7, CYP2G1P, CYP2A7P2, CYP2B7P, AC092071.1, CYP2B6, CYP2A7P1, CYP2G2P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,665 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,336,446–68,952,893, 186 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr2:199,867,396–201,229,406, 48 genes, copy number 16: AC097717.1, RN7SL717P, C2orf69, TYW5, MAIP1, AC004464.1, SPATS2L, RNY4P34, AC012459.1, KCTD18, SGO2, AOX1, AOX3P, AOX3P-AOX2P, LINC01792, AOX2P, RNU1-133P, BZW1-AS1, BZW1, RNU6-31P, BICD1P1, RNA5SP115, CLK1, Y_RNA, PPIL3, RNU6-312P, NIF3L1, RNU6-762P, ORC2, AC005037.1, FAM126B, HNRNPA1P35, RPL23AP30, NDUFB3, RNU6-1206P, Metazoa_SRP, AC007272.1, RPL17P10, CFLAR, IMPDH1P10, CFLAR-AS1, RNU7-45P, RPL38P5, AC007283.1, CASP10, MTND5P25, MTND4P23, MTND4LP13.
- chr5:58,198–45,895,970, 710 genes, copy number 8–13 (broad region; genes not listed).
- chr7:47,275,154–48,711,582, 14 genes, copy number 7 (within-gene range 5–7): TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, LINC02838.
- chr8:35,672,195–38,704,855, 73 genes, copy number 9–15 (broad region; genes not listed).
- chr8:119,214,625–145,066,685, 475 genes, copy number 7 (broad region; genes not listed).
- chr9:30,388,935–30,774,732, 5 genes, copy number 11: LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66.
- chr9:31,165,618–33,410,553, 40 genes, copy number 11: AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23, RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7, AL356218.2.
- chr11:27,978,669–29,276,565, 14 genes, copy number 7: AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758, LINC02742, OR2BH1P, AC090791.1, AC110056.1.
- chr11:29,391,525–29,552,861, 3 genes, copy number 7: AC090124.2, AC090124.1, AC110058.1.
- chr11:91,157,994–93,991,429, 58 genes, copy number 9–18 (within-gene range 6–18): LINC02748, AP003485.2, AP003485.1, AP002791.1, LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1, AP003969.1, AP003969.2, DEUP1, SMCO4, SRP14P2, RN7SL223P, AP003499.5, AP003499.4, AP003499.1, CEP295, Y_RNA, SCARNA9, AP003499.3, AP003499.2, AP001273.1, TAF1D, SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40, C11orf54, AP001273.2, MED17, VSTM5, Y_RNA, AP002795.1.
- chr15:26,866,911–26,970,385, 2 genes, copy number 8: GABRA5, TVP23BP1.
- chr15:27,038,978–27,208,635, 2 genes, copy number 8: GABRG3-AS1, AC136896.1.
- chr15:47,133,495–66,956,518, 451 genes, copy number 7 (broad region; genes not listed).
- chr15:67,000,814–67,001,085, 1 gene, copy number 7: HMGN2P47.
- chr17:50,693,198–83,095,122, 949 genes, copy number 7–8 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 7 (broad region; genes not listed).
- chr19:21,932,958–22,010,949, 1 gene, copy number 7 (within-gene range 3–7): ZNF208.
- chr19:21,965,708–22,532,485, 25 genes, copy number 7 (within-gene range 4–7): AC003973.2, BNIP3P28, AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.14, AC073539.1, AC073539.3, ZNF729, BNIP3P31, AC011494.1, RPL34P34, ZNF98, AC011516.1, BNIP3P32, AC025811.1, BNIP3P33, ZNF209P.
- chr20:31,257,664–36,088,192, 194 genes, copy number 7 (broad region; genes not listed).
- chr21:21,746,973–24,547,942, 31 genes, copy number 9–20: LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684.
- chr21:24,886,676–24,902,756, 1 gene, copy number 9: AP000402.1.
- chr21:46,458,891–46,665,124, 6 genes, copy number 7: DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.

Autosomal genes at a single copy (total copy number 1): 653. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
